Somatic mutation profile of tumor specimen MP2PRT-PANTYP-TMP1-A (aliquot MP2PRT-PANTYP-TMP1-A-1-0-D-A83L-36) from MP2PRT case MP2PRT-PANTYP, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.1 years (1,138 days).
Specimen MP2PRT-PANTYP-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 58237c74-611f-4ad4-a983-07e0d4afe19f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PANTYP-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PANTYP-NB1-A-1-0-D-A83L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6a476c63-0791-48f2-9bc2-b2079c3f0a3a

The open-access MAF lists 17 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 4, Frame Shift Ins 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4337G>A p.R1446H | Missense Mutation (SNP) | VAF 13/389 reads (3%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519884, COSV52112787, COSV52125401, COSV52132241; ClinVar: likely pathogenic; called by muse, mutect2
- CREBBP | c.4336C>T p.R1446C | Missense Mutation (SNP) | VAF 57/343 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs398124146, COSV52113365, COSV52115600, COSV52116725; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ANKRD30A | c.2623G>A p.E875K (on ENST00000611781; = p.E819K on NM_052997.2) | Missense Mutation (SNP) | VAF 73/386 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.692); catalogued as rs1288151210, COSV100653771, COSV100654359; called by muse, mutect2, varscan2
- KATNAL1 | c.1333C>T p.R445C | Missense Mutation (SNP) | VAF 61/351 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs747851515, COSV66065213; called by muse, mutect2, varscan2
- KCNJ4 | c.1186G>A p.A396T | Missense Mutation (SNP) | VAF 41/674 reads (6%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs900150387, COSV57856126; called by muse, mutect2
- LMTK3 | c.2282G>A p.R761Q | Missense Mutation (SNP) | VAF 43/215 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.184); catalogued as rs1333367849, COSV54310722; called by muse, mutect2, varscan2
- NF1 | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 26/502 reads (5%) | SIFT tolerated (0.49); PolyPhen benign (0.061); catalogued as rs758624540, COSV100647293, COSV62205212; ClinVar: likely benign / uncertain significance; called by muse, mutect2
- PLA2G4E | c.397G>A p.V133M | Missense Mutation (SNP) | VAF 30/168 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.916); catalogued as rs759986725, COSV68150401; called by muse, mutect2, varscan2
- COL26A1 | c.301C>T p.P101S (on ENST00000313669 / NM_001278563.3; = p.P99S on NM_133457.4) | Missense Mutation (SNP) | VAF 52/298 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- IGKV3-20 | c.347_348insCACCCTT p.*117Tfs*? | Frame Shift Ins (INS) | VAF 25/108 reads (23%) | called by mutect2, pindel*, varscan2
- PJA1 | c.543G>C p.K181N | Missense Mutation (SNP) | VAF 125/853 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- ESX1 | c.1029G>A p.P343= | Silent (SNP) | VAF 235/1338 reads (18%) | catalogued as rs368249985, COSV65425163; called by muse, mutect2, varscan2
- LCT | c.4431C>T p.I1477= | Silent (SNP) | VAF 31/335 reads (9%) | catalogued as rs745347875; called by muse, mutect2
- LRPAP1 | c.543G>A p.E181= | Silent (SNP) | VAF 25/588 reads (4%) | called by muse, mutect2
- NPAS4 | c.2127C>T p.P709= | Silent (SNP) | VAF 39/532 reads (7%) | catalogued as rs775151559, COSV60649142, COSV60650215; called by muse, mutect2
- DCHS2 | n.176G>A | RNA (SNP) | VAF 35/505 reads (7%) | called by muse, mutect2
- RNU6-1178P | chr17:20895791 C>T | 5'Flank (SNP) | VAF 79/422 reads (19%) | catalogued as rs370316903, COSV60002826; called by muse, mutect2, varscan2
